CCDI case PBBXEU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e445e643-436e-46d5-ae62-69c199bff77d

Demographics
Sex at birth: male; Race: white; Vital status: Dead.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 5.3 years (1,918 days).

Biospecimens (3 samples)
- Sample 0DJXPD: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJXQ9: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DJXRJ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
